Gene-level copy-number profile of tumor specimen TCGA-DX-A6BG-01A from TCGA case TCGA-DX-A6BG, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 51.1 years (18,682 days).
Specimen TCGA-DX-A6BG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.096b01ce-bd04-4d2e-aa9d-155e2ca1e24d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A6BG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/333a1417-864f-4e1f-8891-5a3f8d38dcf0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,386; copy number 2: 56,250; copy number 3: 796; copy number 4: 39; copy number 5: 41; copy number 6: 30; copy number 7: 54; copy number 8: 33; copy number 9: 37; copy number 10: 26; copy number 11: 24; copy number 12: 14; copy number 13: 7; copy number 14: 35; copy number 15: 1; copy number 16: 5; copy number 17: 6; copy number 18: 15; copy number 19: 1; copy number 20: 5; copy number 21: 5; copy number 23: 2; copy number 24: 2; copy number 25: 2; copy number 30: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A6BG-01A-11D-A306-01): tumor purity 0.25, ploidy 2.13, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 346 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:22,266,239–22,366,482, 3 genes, copy number 6: MIR4418, PPIAP34, AL591122.1.
- chr1:56,929,207–56,996,757, 2 genes, copy number 14: C8B, AL161740.1.
- chr1:57,860,532–58,229,003, 6 genes, copy number 8–17: DAB1-AS1, HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1, AL357373.1.
- chr1:59,289,303–59,289,640, 1 gene, copy number 14: AC093424.1.
- chr1:166,665,885–168,495,685, 48 genes, copy number 9–18: FMO10P, RPL4P2, FMO11P, CNN2P10, POGK, TADA1, DUTP6, ILDR2, MAEL, RNA5SP65, AL158837.1, GPA33, STYXL2, AL451050.1, LINC01363, AL451050.2, POU2F1, AL136984.1, CD247, AL359962.3, AL359962.1, AL359962.2, AKR1D1P1, CREG1, AL031733.1, AL031733.2, RCSD1, MPZL1, ADCY10, Z99943.2, Z99943.1, MPC2, DCAF6, MIR1255B2, GCSHP5, GPR161, TIPRL, RPL34P1, AL021397.1, SFT2D2, ANKRD36BP1, RNU6-1310P, TBX19, AL022100.1, MIR557, AL023755.1, AL022100.2, QRSL1P1.
- chr1:170,662,728–170,739,421, 2 genes, copy number 10 (within-gene range 3–10): PRRX1, Z97200.1.
- chr1:171,600,621–172,444,086, 21 genes, copy number 5–7 (within-gene range 2–7): MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC.
- chr2:143,601,517–143,776,119, 4 genes, copy number 11: AC092652.2, ARHGAP15-AS1, AC092652.1, AC079584.2.
- chr5:38,474,668–39,103,677, 11 genes, copy number 12: LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1.
- chr5:101,581,830–105,392,970, 33 genes, copy number 5–14 (within-gene range 2–14): RN7SL802P, OR7H2P, AC117525.1, RNA5SP188, AC008948.1, SLCO4C1, RN7SKP68, SLCO6A1, AC094108.1, LINC00492, LINC00491, AC099487.1, AC099487.2, PAM, EIF3KP1, GIN1, PPIP5K2, AC011362.1, MACIR, AC010406.1, PDZPH1P, LINC02115, NUDT12, AC008505.1, LINC02163, RNU1-140P, RN7SL255P, AC099520.1, AC091931.1, AC099520.2, RNU6-334P, AC091987.1, RAB9BP1.
- chr5:145,228,811–145,230,054, 1 gene, copy number 6: ASS1P10.
- chr12:55,444,069–55,470,138, 2 genes, copy number 25: OR6C2, OR6C70.
- chr12:57,738,013–58,395,138, 28 genes, copy number 11–19: TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1.
- chr12:65,758,020–65,826,997, 1 gene, copy number 13: RPSAP52.
- chr12:65,830,750–65,831,050, 1 gene, copy number 13: AC107308.1.
- chr12:68,674,371–68,971,570, 14 genes, copy number 5–20 (within-gene range 2–20): AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,348,381–69,584,823, 9 genes, copy number 18: LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2.
- chr12:69,825,227–71,118,247, 18 genes, copy number 6–18 (within-gene range 2–18): MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2.
- chr12:71,582,293–71,594,404, 2 genes, copy number 23: AC078860.3, AC078860.2.
- chr12:71,754,863–71,927,248, 5 genes, copy number 21 (within-gene range 3–21): RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2.
- chr12:72,431,722–72,728,844, 3 genes, copy number 12–30: H3P35, CHCHD3P2, AC133480.1.
- chr12:73,758,657–73,846,188, 1 gene, copy number 13 (within-gene range 2–13): LINC02445.
- chr12:73,820,315–74,545,430, 9 genes, copy number 8–24: LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1.
- chr12:75,020,969–75,209,839, 2 genes, copy number 5–7 (within-gene range 5–26): AC073525.1, KCNC2.
- chr12:78,326,680–78,808,995, 6 genes, copy number 16–17: LINC02424, AC128707.1, AC130415.1, AC079362.1, AC068993.1, AC068993.2.
- chr12:82,358,528–82,479,239, 1 gene, copy number 12 (within-gene range 2–12): METTL25.
- chr12:84,859,491–84,913,615, 1 gene, copy number 10: SLC6A15.
- chr12:85,280,220–85,342,912, 2 genes, copy number 6 (within-gene range 2–20): ALX1, LINC02820.
- chr12:106,170,004–106,172,437, 1 gene, copy number 9: AC010182.1.
- chr15:73,051,710–73,305,205, 4 genes, copy number 6 (within-gene range 2–6): NEO1, FKBP1AP2, NPM1P43, AC068397.1.
- chr15:82,041,778–82,262,734, 6 genes, copy number 5 (within-gene range 2–5): MEX3B, LINC01583, AC026956.2, EFL1, RNU1-77P, AC026624.1.
- chr16:8,276,263–8,797,642, 15 genes, copy number 5–16 (within-gene range 4–16): AC018767.2, LINC02152, AC018767.3, AC018767.1, AC074052.1, AC074052.2, TMEM114, AC138420.1, METTL22, AC007224.2, ABAT, RN7SL743P, RNU7-63P, AC007224.1, TMEM186.
- chr18:30,290,161–30,414,073, 1 gene, copy number 5 (within-gene range 2–5): AC115100.1.
- chr20:37,903,111–41,383,107, 73 genes, copy number 5–15 (broad region; genes not listed).
- chr20:46,345,980–46,550,654, 9 genes, copy number 7: SLC35C2, AL133227.1, ELMO2, ZNF663P, AL031686.1, MKRN7P, ZNF840P, ZNF334, OCSTAMP.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
